Gene-level copy-number profile of tumor specimen TCGA-YL-A9WY-01A from TCGA case TCGA-YL-A9WY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.9 years (21,164 days).
Specimen TCGA-YL-A9WY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ef86f189-4581-438e-a5f6-dc6bf13af20b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A9WY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/10a654f2-ea11-49a0-b90a-f4a64ba89760

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 60; copy number 2: 8,692; copy number 3: 12,854; copy number 4: 35,052; copy number 5: 227; copy number 6: 1,513; copy number 7: 428; copy number 8: 294; copy number 9: 20; copy number 10: 456; copy number 11: 150.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A9WY-01A-11D-A41J-01): tumor purity 0.3, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:73,995,193–74,121,363, 1 gene (within-gene range 0–2): VCL.
- chr10:74,120,255–76,560,994, 45 genes: AP3M1, ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1, FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1.
- chr10:87,341,685–88,584,530, 25 genes (within-gene range 0–2): LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 626 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,798,804–69,104,242, 64 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).
- chr8:72,947,150–76,867,281, 69 genes, copy number 9–10 (within-gene range 7–10) (broad region; genes not listed).
- chr8:90,791,741–90,959,393, 1 gene, copy number 10 (within-gene range 8–10): NECAB1.
- chr8:90,958,471–104,256,094, 277 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr8:106,697,427–107,648,032, 10 genes, copy number 9: TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13.
- chr17:18,087,892–19,378,193, 86 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:19,904,302–22,606,703, 119 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
